Gene-level copy-number profile of tumor specimen TCGA-AZ-5403-01A from TCGA case TCGA-AZ-5403, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 43.8 years (15,983 days).
Specimen TCGA-AZ-5403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ebea1b5d-cd2b-47b9-92c8-641009739dfe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-5403-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f9ef0d7-0655-4ebd-9144-4f5d8140dac0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,616; copy number 2: 35,611; copy number 3: 7,299; copy number 4: 5,317; copy number 5: 1,718; copy number 6: 96; copy number 7: 162.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AZ-5403-01A-01D-1649-01): tumor purity 0.38, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,976 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,955,014–8,574,038, 27 genes, copy number 5 (within-gene range 4–5): FAM66E, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.3, AC105233.4, AC105233.5, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P, PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1.
- chr8:38,062,881–39,417,378, 42 genes, copy number 7: AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:40,900,016–63,693,249, 346 genes, copy number 5–6 (broad region; genes not listed).
- chr8:63,703,077–63,813,937, 2 genes, copy number 6: AC069133.1, LINC01289.
- chr8:106,215,763–145,066,685, 578 genes, copy number 5 (broad region; genes not listed).
- chr20:23,875,934–64,313,132, 981 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
